Surgical pathology report (de-identified scan), TCGA case TCGA-98-A539, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A539-01A (Primary Tumor).

[page 1 of 3]
Patient Name	MR#	Observation Date	Last Edited Date
--------------	-----	------------------	------------------

SURGICAL PATHOLOGY CASE:

Diagnosis

- A. Tonsil, left, biopsy: - Negative for malignancy.
- B. Lymph node, 7, excision: - Negative for malignancy.
- C. Lymph node, 9, excision:- Negative for malignancy.
- D. Lymph node, 8, excision: - Negative for malignancy.
- E. Lymph node, 11-L: - Negative for malignancy.,
- F. Lymph node, level 5, excision: - Negative for malignancy.
- G. Lymph node, level 6, excision: Negative for malignancy.
- H. Soft tissue, anterior margin between ribs 4 and 5, excision: Negative for malignancy.
- I. Soft tissue, anterior margin from rib 3, excision: - Negative for malignancy.
- J. Soft tissue, extrathoracic, excision: Squamous cell carcinoma.
- K. Soft tissue, posterior margin rib 3, biopsy: - Negative for malignancy.
- L. Soft tissue, serratus muscle, biopsy:- Positive for squamous cell carcinoma.
- M. Soft tissue, second rib, excision: - Positive for invasive squamous cell carcinoma within the marrow aspect of the bony tissue.
- N. Soft tissue, intercostal muscle between ribs 1 and 2, excision: - Squamous cell carcinoma present.
- O. Soft tissue, middle scalene muscle, excision: - Positive for squamous cell carcinoma.
- P. Lung, left upper lobe wedge and parts of ribs 2 and 3, excision: - Squamous cell carcinoma (4.5 cm). - Negative margins at staple line. - Pleura is uninvolved. - Lymph nodes are negative, please see detailed list.
- Q. Pleura, biopsy: - Negative for malignancy.
- R. Lymph node, 5, excision: - Negative for malignancy. pT3, N0, Mx

ICD-O-3

carcinoma, squamous cell, NOS 8070/3

Site: lung, upper lobe c34.1

hw
11/25/12

Clinical Information: The patient is a year-old male with lung cancer.

Frozen Section Diagnosis

- A1: Tonsil, left, biopsy: - Negative for malignancy.
- B1: Lymph node, #7, excision:- Negative for malignancy.
- C1: Lymph node, #9, excision: - Negative for malignancy.
- D1: Lymph node, #8, excision: - Negative for malignancy.
- F1: Lymph node, level 5, excision: - Negative for malignancy.

[page 2 of 3]
G1: Lymph node, level 6, excision: - Negative for malignancy.
H1: Soft tissue, anterior margin between ribs 3 and 4, excision: - Negative for malignancy.
J1: Soft tissue, extrathoracic, excision: - Squamous cell carcinoma.
K1: Soft tissue, posterior margin rib 3, biopsy: - Negative for malignancy.
L1: Soft tissue, part of serratus muscle, biopsy: - Positive for squamous cell carcinoma.
P1: Lung, left upper lobe wedge and part of ribs 2 and 3, excision: - Tumor grossly 0.5 cm from the nearest staple line margin. (all per

Gross Description

The specimen is received in eighteen containers, each labeled with the patient's name and medical record number. The first container is further labeled "biopsy of tonsil." Specimen is received fresh in frozen, now in formalin, and contains one pink fragment of tissue measuring 0.5 x 0.5 x 0.5 cm. It contains a cassette containing material for previous evaluation. The tissue is resubmitted entirely in cassette A1.

The second container is labeled "level 7." Specimen is received fresh in the frozen room, now in formalin, and contains a cassette containing previous material for previous frozen evaluation which measures 0.5 x 0.5 x 0.2 cm. Specimen is submitted entirely in cassette B1.

The third container is labeled "lymph node #9." Specimen is received fresh in frozen room, now in formalin, and contains a cassette containing material for previous frozen evaluation which measures 1.5 x 1.0 x 0.3 cm. Specimen is entirely submitted in cassette C1.

The fourth container is labeled "lymph node #8." Specimen is received fresh in frozen room, now in formalin, and contains a cassette containing material for previous frozen evaluation measuring 1.0 x 0.6 x 0.3 cm. Specimen is entirely submitted in cassette D1.

The fifth container is labeled "lymph node #11-L." It contains a dark brown color irregular shape soft tissue measuring 1.0 x 0.8 x 0.3 cm. Specimen is entirely submitted in cassette E1.

The sixth container labeled "level 5 lymph node." The specimen is received fresh in frozen room, now in formalin, and contains a cassette containing material for previous frozen evaluation which measures 1.0 x 0.8 x 0.2 cm. Specimen is submitted entirely in cassette F1.

The seventh container is labeled "level 6 lymph node." The specimen is received fresh in frozen room, now in formalin, and contains a cassette containing material for previous frozen evaluation measuring 2.5 x 1.0 x 0.2 cm. Specimen is submitted entirely in cassette G1.

The eighth container is labeled "anterior margin between ribs 4 and 5." Specimen is received fresh in frozen room, now in formalin, and contains red tissue measuring 0.8 x 0.7 x 0.2 cm. Specimen is submitted entirely in cassette H1.

The ninth container is labeled "anterior margin from rib 3." It contains a bone and soft tissue measuring 1.2 x 1.2 x 0.3 cm. The submitted is submitted entirely in cassette I1 after decalcification.

The tenth container is labeled "extrathoracic tissue." It contains a specimen received fresh in frozen room, now in formalin, and contains one cassette containing material for previous frozen evaluation measuring 1.5 x 1.2 x 0.3 cm. Specimen is resubmitted entirely in cassette J1.

The eleventh container is labeled "posterior margin of rib 3." Specimen is received fresh in frozen room, now in formalin, and contains a cassette containing material for previous frozen evaluation which measures 0.8 x 0.6 x 0.2 cm. Specimen is resubmitted entirely in cassette K1.

The twelfth container is labeled "part of serratus muscle." Specimen is received fresh in the frozen room, now in formalin, and contains a cassette containing material from previous frozen evaluation which measures 3.5 x 2.5 x 0.3 cm. Specimen is resubmitted entirely in cassette L1.

The thirteen container is labeled "part of second rib." It contains a piece of rib measuring 6 x 2 x 1.5 cm. It contains muscle and part of the bone. The specimen is submitted entirely in cassette M1-M10 after decalcification.

The fourteen container is labeled "intercostal muscle between ribs 1 and 2." It contains a piece of pink-red fibroadipose tissue measuring 3.0 x 2.2 x 1.3 cm. Specimen is not oriented. Serial sectioning reveals pink-red-tan surface. Specimen is submitted entirely in cassettes N1-N5.

[page 3 of 3]
The fifteen container is labeled "middle scalene muscle." It contains a piece of pink-red tissue measuring 2.7 x 1.8 x 1.5 cm. Specimen is not oriented. Surgical margin will be inked black. Serial sectioning reveals pink-red cutting surface. Representative sections of the specimen will be submitted entirely O1-O5.

The sixteen container is further labeled "left upper lobe wedge and part of ribs 2 and 3." It contains a lung wedge biopsy with attached chest wall and rib. The lung measuring 12.0 x 7.5 x 2.5 cm and the chest wall measuring 11.0 x 7.5 x 2.0 cm. Staple line margin is identified measuring 12.0 cm in length. The staple line is shaved and inked black. Serial sectioning through the lung wedge reveals a tan-white necrotic tumor measuring 4.5 cm in greatest dimension and approximately 0.5 cm from the inked margin anterior invades deep into the chest wall and right abuts the outer surface. The entire outer surface of the chest will be inked green. The tumor appears to involve the anterior and part of the chest wall, lateral margin. However, the superior end inferior margin cannot be clear oriented. The tumor is approximately 1.1 cm from the lateral margin. Representative sections will be submitted per block summary.

The seventeen container is labeled "pleura." It contains a piece of bone with associated soft tissue measuring 2.5 x 2.0 x 0.8 cm. Specimen is submitted after decalcification.

The eighteen container labeled "lymph node #5." It contains one pink-red fibroadipose tissue measuring 1.3 x 1.0 x 0.5 cm. Specimen is serially sectioned submitted entirely in cassette R1.

Block Summary

A1- Biopsy tonsil
B1- Lymph node 7
C1- Lymph node 9
D1- Lymph node 8
E1- Lymph node 11-L
F1- Lymph node 5
G1- Lymph node 6
H1- Anterior margin between ribs 4 and 5.
I1- Anterior margin from rib 3.
J1- Extrathoracic tissue
K1- Posterior margin, rib 3.
L1- Part of serratus muscle
M1-M10 Part of 2nd rib.
N1- Intercostal muscle between ribs 1 and 2.
O1-O5 Middle scalene muscle.
P1-P2 Tumor related to the inked staple margin.
P3- Representative sections of tumor.
P4-P5 Tumor related to the anterior margin.
P6-P7 Tumor related to the lateral margin.
P8- Uninvolved lung.
P9- Superior inferior margin.
Q1-Q2 Pleura.
R1 Lymph node #5

Microscopic Description

A microscopic examination has been performed.

HPA Discrepancy		☒
Prior Malignancy History	ONE - OK	☒

Source: NCI Genomic Data Commons file 84f30167-70d3-49cc-8aad-656f0547fe15 (TCGA-98-A539.9CC9A747-F186-4BAE-B63F-82DC061B06FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).